Gene-level copy-number profile of tumor specimen ALCH-B2ND-TTP1-A from ALCHEMIST case ALCH-B2ND, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.6 years (21,409 days).
Specimen ALCH-B2ND-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b77bde37-0a40-411d-81b6-a3aab2cc1a4e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2ND-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/6b46262f-da2e-4c90-96b2-74e8c6988a1d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 22,683; copy number 2: 28,174; copy number 3: 5,495; copy number 4: 1,955; copy number 5: 36; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,370,448–75,625,188, 15 genes: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, AC108724.2.
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr5:180,945,756–181,007,384, 6 genes (within-gene range 0–1): RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr9:14,921,013–15,146,401, 1 gene (within-gene range 0–1): CLCN3P1.
- chr9:14,993,312–15,143,386, 3 genes: AL592293.1, PSIP1P1, RNU6-559P.
- chr9:21,994,139–22,128,103, 6 genes (within-gene range 0–1): CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr13:63,183,096–63,328,129, 1 gene: LINC00376.
- chr16:69,311,350–69,339,583, 4 genes (within-gene range 0–2): VPS4A, COG8, PDF, AC026464.6.
- chr19:1,228,287–1,239,522, 2 genes (within-gene range 0–1): CBARP, AC004221.1.
- chr22:22,792,491–22,812,281, 3 genes (within-gene range 0–2): IGLV2-11, AC245028.3, IGLV3-10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–190,892,429, 19 genes, copy number 5: TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr6:60,281,444–60,546,660, 1 gene, copy number 6: AC244258.1.
- chr6:63,193,072–63,779,336, 16 genes, copy number 5 (within-gene range 3–5): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 1–5): GATD3A.

Autosomal genes at a single copy (total copy number 1): 20,368. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
